Somatic mutation profile of tumor specimen TCGA-3A-A9IS-01A (aliquot TCGA-3A-A9IS-01A-21D-A397-08) from TCGA case TCGA-3A-A9IS, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 67.4 years (24,621 days).
Specimen TCGA-3A-A9IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d76d4c5b-e103-44c8-906a-f8ff571db192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IS-10A (Blood Derived Normal), aliquot TCGA-3A-A9IS-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2f2e0b3-a20c-446a-944d-d4f7effac7de

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMH | c.678T>G p.S226R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV99678089; called by muse, mutect2
- ATRX | c.6797T>G p.L2266W | Missense Mutation (SNP) | VAF 374/386 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100971361; called by muse, mutect2, varscan2
- BDKRB1 | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 176/612 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as COSV99388023; called by muse, mutect2, varscan2
- CCDC138 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 125/301 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV99719495; called by muse, mutect2, varscan2
- DKC1 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV101059900; called by muse, mutect2
- ESPL1 | c.5819G>A p.S1940N | Missense Mutation (SNP) | VAF 31/481 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs774946140, COSV99229729; called by muse, mutect2
- FBN2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 110/510 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1356151682, COSV99329249, COSV99330427; called by muse, mutect2, varscan2
- FN1 | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs181283286; called by muse, mutect2, varscan2
- GALNT18 | c.1356G>T p.W452C | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1394837181, COSV99925776; called by muse, mutect2, varscan2
- GTF3C4 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 215/866 reads (25%) | catalogued as COSV100936081; called by muse, mutect2, varscan2
- HELZ2 | c.4216A>T p.M1406L (on ENST00000467148 / NM_001037335.2; = p.M837L on NM_033405.3) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101427618; called by muse, mutect2, varscan2
- HRH3 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1466564594, COSV100420715; called by muse, mutect2, varscan2
- KMT2E | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 107/363 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as COSV99996938; called by muse, mutect2, varscan2
- MMAA | c.548_550del p.S183del | In Frame Del (DEL) | VAF 260/1312 reads (20%) | catalogued as rs748291856; called by pindel, varscan2
- NAA16 | c.1080C>A p.S360R | Missense Mutation (SNP) | VAF 136/731 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.493); catalogued as rs765557946, COSV101038411; called by muse, mutect2, varscan2
- NF1 | c.2976G>A p.M992I | Missense Mutation (SNP) | VAF 156/486 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1190931765, COSV100648179; called by muse, mutect2, varscan2
- PAX9 | c.438C>A p.H146Q | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as COSV100825621, COSV100825882; called by muse, mutect2, varscan2
- PGGT1B | c.960G>C p.L320F | Missense Mutation (SNP) | VAF 84/391 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.611); catalogued as COSV99686047; called by muse, mutect2, varscan2
- SNAP47 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs140772937, COSV59919748; called by muse, mutect2, varscan2
- SNAP47 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1283561107, COSV100248467; called by muse, mutect2, varscan2
- SRFBP1 | c.977C>A p.T326K | Missense Mutation (SNP) | VAF 129/254 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100232955; called by muse, mutect2, varscan2
- UBN2 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99944425; called by muse, mutect2, varscan2
- WDR3 | c.1045del p.L349Cfs*8 | Frame Shift Del (DEL) | VAF 169/485 reads (35%) | catalogued as COSV62525580; called by mutect2, pindel, varscan2
- WDR5 | c.631+1G>A p.X211_splice | Splice Site (SNP) | VAF 238/808 reads (29%) | catalogued as rs112881246, COSV100682030; called by muse, mutect2, varscan2
- ZNF692 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100133933; called by muse, mutect2, varscan2
- ABCA4 | c.6370del p.V2124Sfs*21 | Frame Shift Del (DEL) | VAF 102/340 reads (30%) | called by mutect2, pindel, varscan2
- TNFRSF11A | c.1572_1575delinsA p.N524_V525delinsK | In Frame Del (DEL) | VAF 36/127 reads (28%) | called by pindel, varscan2*
- ZNF577 | c.1332del p.P445Qfs*7 | Frame Shift Del (DEL) | VAF 83/316 reads (26%) | called by mutect2, pindel, varscan2
- ACAD10 | c.1077C>T p.P359= | Silent (SNP) | VAF 432/1036 reads (42%) | catalogued as rs1209936947, COSV100564570; called by muse, mutect2, varscan2
- BPIFB2 | c.378C>T p.S126= | Silent (SNP) | VAF 89/377 reads (24%) | catalogued as COSV99401657; called by muse, mutect2, varscan2
- DAZAP1 | c.564T>A p.A188= | Silent (SNP) | VAF 37/367 reads (10%) | catalogued as rs1224428403, COSV99245461; called by muse, mutect2
- GCG | c.189C>T p.S63= | Silent (SNP) | VAF 104/709 reads (15%) | catalogued as COSV64961244; called by muse, mutect2, varscan2
- KCNT1 | c.633G>A p.P211= (on ENST00000488444; = p.P230= on NM_020822.3) | Silent (SNP) | VAF 166/509 reads (33%) | catalogued as rs565506288, COSV99706595; called by muse, mutect2, varscan2
- RNF181 | c.9C>T p.S3= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs745317948, COSV100110603; called by muse, mutect2, varscan2
- ZFYVE28 | c.528C>G p.V176= | Silent (SNP) | VAF 48/251 reads (19%) | catalogued as COSV99343624; called by muse, mutect2, varscan2
- ZNF334 | c.79C>T p.L27= | Silent (SNP) | VAF 130/623 reads (21%) | catalogued as rs1442970849, COSV100749198; called by muse, mutect2, varscan2
- KCNK7 | c.718+41G>C | Intron (SNP) | VAF 86/195 reads (44%) | catalogued as COSV58421748; called by muse, mutect2, varscan2
